TCGA case TCGA-AF-2687 — Rectum Adenocarcinoma (TCGA-READ)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectosigmoid junction; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f9204a59-6877-4d06-a20e-fd7ab0859ed5

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 57 years; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C19; Tissue or organ of origin: Rectosigmoid junction; Site of resection or biopsy: Rectum, NOS; Classification of tumor: primary; Age at diagnosis: 57.8 years (21,098 days); Year of diagnosis: 2009; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,427 days (3.9 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 6; Lymph nodes tested: 16; Lymphatic invasion present: Yes; Non nodal tumor deposits: Yes; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine; Treatment intent type: Adjuvant; Days to treatment start: 55 days; Days to treatment end: 97 days; Treatment dose: 93,000 mg; Prescribed dose: 1500; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 56 days; Days to treatment end: 97 days; Treatment dose: 5,040 cGy; Course number: 1; Number of fractions: 28; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Adjuvant; Days to treatment start: 133 days; Days to treatment end: 261 days; Number of cycles: 9; Treatment dose: 34,193 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Adjuvant; Days to treatment start: 133 days; Days to treatment end: 259 days; Number of cycles: 9; Treatment dose: 5,699 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Leucovorin; Treatment intent type: Adjuvant; Days to treatment start: 133 days; Days to treatment end: 259 days; Number of cycles: 9; Treatment dose: 5,750 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Treatment intent type: Adjuvant; Days to treatment start: 133 days; Days to treatment end: 259 days; Number of cycles: 9; Treatment dose: 1,211 mg; Route of administration: Intravenous.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 61.2 years (22,365 days); Days to diagnosis: 1,267 days (3.5 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS; Surgery, NOS.

Follow-up (4 entries)
- Days to follow up: 595 days (1.6 years); Disease response: Tumor Free.
- Days to follow up: 734 days (2.0 years); Disease response: Tumor Free.
- Day 1,267 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 1,427 days (3.9 years); Disease response: Tumor Free.

Molecular and laboratory tests
- CEA: 5.3 ng/mL.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 68.2 kg; Height: 163 cm; BMI: 25.7.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AF-2687-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.8; Intermediate dimension: 0.8; Shortest dimension: 0.4.
  Slide TCGA-AF-2687-01A-02-BS2: Section location: Bottom; Percent tumor cells: 42; Percent tumor nuclei: 70; Percent normal cells: 50; Percent necrosis: 3; Percent stromal cells: 5.
  Slide TCGA-AF-2687-01A-01-BS1: Section location: Top; Percent tumor cells: 45; Percent tumor nuclei: 70; Percent normal cells: 40; Percent necrosis: 10; Percent stromal cells: 5.
- Sample TCGA-AF-2687-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AF-2687-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Rectum; Histologic diagnosis: Rectal Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Anatomic organ subdivision: Rectum; Lymph nodes examined: Yes; CEA level pretreatment: 5.3; Lymphovascular invasion indicator: Yes; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: No; Colon polyps at procurement indicator: No.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: Xeloda.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Regimen number: 2; Pharmaceutical therapy drug name: 5 FU.
- Drug treatment 2, Route of administrations: Route of administration: IV.
- Follow-up form 1: Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Follow-up form 3: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: Yes.
- Follow-up form 3, New tumor event: New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,427 days; disease-specific survival: no event (censored), 1,427 days; disease-free interval: event (new tumor event after initially disease-free), 1,267 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,267 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AF-2687-01A-02D-1732-01): tumor purity 0.44, ploidy 2.8, whole-genome doublings 1.
